TCGA case TCGA-C4-A0EZ — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/05935f1d-77c2-46ca-b87a-7a84bce38afd

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age at index: 68 years; Vital status: Dead; Days to death: 273 days.

Diagnoses (2)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 69.0 years (25,202 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; AJCC staging edition: 5th; AJCC pathologic T: T3a; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 273 days.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Etoposide; Days to treatment start: 123 days; Days to treatment end: 212 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Days to treatment start: 243 days; Days to treatment end: 243 days; Treatment outcome: Partial Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Lower limb, NOS; Classification of tumor: Prior primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 273 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 76 kg; Height: 169 cm; BMI: 26.6.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 34; Age at onset: 29.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-C4-A0EZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 210 mg.
  Slide TCGA-C4-A0EZ-01A-02-BS2: Section location: Bottom; Percent tumor cells: 89; Percent tumor nuclei: 97; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 1; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-C4-A0EZ-01A-01-BS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 80; Percent normal cells: 44; Percent necrosis: 2; Percent stromal cells: 5; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-C4-A0EZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-C4-A0EZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Tobacco smoking history indicator: 2; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Method initial path diagnosis: Other method, specify:.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Partial Remission/Response; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Lower Limb; Other malignancy histological type: Malignant Melanoma of Skin.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -6117.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Patient had a melanoma of the lower limb. No radiation or systemic chemotherapy.

The TCGA Pan-Cancer Clinical Data Resource (Liu et al., Cell 2018) lists this case as redacted by TCGA at the time of its curation; its follow-up endpoints are therefore not restated here.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-C4-A0EZ-01A-21D-A10T-01): tumor purity 0.93, ploidy 3.28, whole-genome doublings 1.
